Somatic mutation profile of tumor specimen MP2PRT-PAVUAK-TBP1-A (aliquot MP2PRT-PAVUAK-TBP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVUAK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,211 days).
Specimen MP2PRT-PAVUAK-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73a48d68-4208-46fd-a6b4-ff4519670fed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUAK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUAK-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d3363e-2222-4883-b107-36f571cc4ef3

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MPDZ | c.279T>A p.F93L | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1179156777; called by muse, mutect2
- RBMXL3 | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 24/838 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs781984868; called by muse, mutect2
- ZNF528 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as rs202043315; called by muse, mutect2
- C1QL2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 36/708 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- LMTK3 | c.3319C>A p.L1107M | Missense Mutation (SNP) | VAF 44/812 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PRDM16 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 17/528 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRFN4 | c.1464C>T p.A488= | Silent (SNP) | VAF 37/739 reads (5%) | called by muse, mutect2
- MYH14 | c.4089C>T p.A1363= | Silent (SNP) | VAF 36/592 reads (6%) | catalogued as rs774053333; ClinVar: uncertain significance; called by muse, mutect2
